Somatic mutation profile of tumor specimen TCGA-56-A4BW-01A (aliquot TCGA-56-A4BW-01A-11D-A24D-08) from TCGA case TCGA-56-A4BW, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 55.6 years (20,301 days).
Specimen TCGA-56-A4BW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f68b123-763d-4f35-8d1f-3505a32a8b04.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-A4BW-10A (Blood Derived Normal), aliquot TCGA-56-A4BW-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31739152-50da-42a3-b550-04d8d845c9f6

The open-access MAF lists 246 somatic variants for this specimen: 190 protein-altering or splice-affecting, 51 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 163, Silent 51, Nonsense Mutation 11, Frame Shift Del 7, Splice Site 5, Frame Shift Ins 2, 3'UTR 2, Intron 1, Splice Region 1, RNA 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.1611G>A p.M537I | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1057519799, COSV60641421, COSV60655080; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.673-1G>T p.X225_splice | Splice Site (SNP) | VAF 7/46 reads (15%) | hotspot (GDC flag); catalogued as rs878854073, CS011061, COSV52662773, COSV52705331, COSV52707963, COSV53154363; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 13/65 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.3415T>A p.W1139R | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100382824; called by muse, mutect2, varscan2
- ABCB5 | c.1789G>T p.D597Y (on ENST00000404938 / NM_001163941.2; = p.D152Y on NM_178559.6) | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs1396616079, COSV51716847, COSV99327794; called by muse, mutect2, varscan2
- AC098582.1 | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99985400; called by muse, mutect2, varscan2
- AC098582.1 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99985402; called by muse, mutect2, varscan2
- ACAN | c.5987G>A p.G1996E | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100717433; called by muse, mutect2, varscan2
- ADCY9 | c.3607G>C p.E1203Q | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99569591; called by muse, mutect2, varscan2
- ADGRF1 | c.1372A>G p.I458V | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV99347093; called by muse, mutect2, varscan2
- AGMO | c.625G>T p.G209C | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100693834; called by muse, mutect2, varscan2
- AHRR | c.1276C>G p.L426V | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV100326809; called by muse, mutect2, varscan2
- APCS | c.28G>T p.V10F | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV99661226; called by muse, mutect2, varscan2
- ARMC10 | c.887A>G p.H296R | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs754378873, COSV100085681; called by muse, mutect2, varscan2
- ATP10D | c.4091C>G p.A1364G | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99903213; called by muse, mutect2, varscan2
- ATP13A1 | c.3098G>A p.R1033H | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs943778890, COSV99179130; called by muse, mutect2, varscan2
- ATP13A1 | c.2717G>A p.G906D | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV99179131; called by muse, mutect2, varscan2
- ATRNL1 | c.2350G>T p.A784S | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV100744581; called by muse, mutect2, varscan2
- BEST3 | c.545G>T p.W182L | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99876130; called by muse, mutect2, varscan2
- BMP10 | c.1106A>T p.H369L | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99770332; called by muse, mutect2, varscan2
- BMPER | c.1929C>G p.I643M | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as COSV51825705; called by muse, mutect2, varscan2
- BNIP3 | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV64044194; called by muse, mutect2, varscan2
- BOC | c.667+1G>T p.X223_splice | Splice Site (SNP) | VAF 60/140 reads (43%) | catalogued as COSV56357425, COSV99848382; called by muse, mutect2, varscan2
- BPIFB1 | c.322C>G p.L108V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV99487263; called by muse, mutect2, varscan2
- BRINP1 | c.2104C>T p.R702* | Nonsense Mutation (SNP) | VAF 25/102 reads (25%) | catalogued as rs1367965685, COSV56303475; called by muse, mutect2, varscan2
- C5orf22 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.382); catalogued as COSV100323426; called by muse, mutect2, varscan2
- CACNA1H | c.4696G>T p.E1566* | Nonsense Mutation (SNP) | VAF 75/146 reads (51%) | catalogued as COSV100671331; called by muse, mutect2, varscan2
- CCDC93 | c.531G>T p.K177N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100098505; called by muse, mutect2, varscan2
- CEACAM6 | c.650T>C p.I217T | Missense Mutation (SNP) | VAF 105/192 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs782639699, COSV99555474, COSV99555683; called by muse, mutect2, varscan2
- CEP192 | c.3637G>T p.G1213C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV100380845; called by muse, mutect2, varscan2
- CHD7 | c.3263T>G p.L1088W | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101418082; called by muse, mutect2, varscan2
- CLVS1 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs202238473, COSV57981325; called by muse, mutect2, varscan2
- CMYA5 | c.9850G>T p.G3284* | Nonsense Mutation (SNP) | VAF 22/67 reads (33%) | catalogued as COSV101483950; called by muse, mutect2, varscan2
- COL22A1 | c.3717A>G p.P1239= | Splice Region (SNP) | VAF 20/79 reads (25%) | catalogued as COSV100277124; called by muse, mutect2, varscan2
- COL22A1 | c.1650A>T p.R550S | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.259); catalogued as COSV100277125; called by muse, mutect2, varscan2
- COL3A1 | c.3952G>C p.D1318H | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100482706, COSV58581811; called by muse, mutect2, varscan2
- CSMD3 | c.353A>G p.Y118C | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as rs1215430049, COSV99828579; called by muse, mutect2, varscan2
- CSMD3 | c.51G>A p.W17* | Nonsense Mutation (SNP) | VAF 45/152 reads (30%) | catalogued as COSV99828580; called by muse, mutect2, varscan2
- CUX2 | c.268C>A p.L90M | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99918421, COSV99919037; called by muse, mutect2, varscan2
- CX3CL1 | c.956T>A p.M319K | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV99136278; called by muse, mutect2, varscan2
- DCHS1 | c.1027C>G p.L343V | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.616); catalogued as COSV100201761; called by muse, mutect2, varscan2
- DDX19A | c.410C>G p.S137C | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100156212; called by muse, mutect2, varscan2
- DDX60 | c.3890G>T p.G1297V | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101190309; called by muse, mutect2, varscan2
- DECR2 | c.670C>G p.Q224E | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV99557061; called by muse, mutect2, varscan2
- DEGS1 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV60378721, COSV60380209; called by muse, mutect2, varscan2
- DLGAP2 | c.869G>T p.R290L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs768915315, COSV101421393; called by muse, mutect2
- DNAH9 | c.11582G>T p.R3861L | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52348202, COSV99304858; called by muse, mutect2, varscan2
- EPHA3 | c.2461G>T p.G821* | Nonsense Mutation (SNP) | VAF 48/124 reads (39%) | catalogued as COSV100343895, COSV60722639; called by muse, mutect2, varscan2
- EPHA6 | c.2326A>T p.S776C (on ENST00000389672 / NM_001080448.3; = p.S168C on NM_173655.4) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs778845618, COSV101061324, COSV67574509; called by muse, mutect2, varscan2
- ETNPPL | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56595024, COSV99625068; called by muse, mutect2
- FAM13B | c.1320G>C p.L440F | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0.408); catalogued as COSV99221136; called by muse, mutect2, varscan2
- FANCI | c.2822_2824del p.G941del (on ENST00000310775 / NM_001376911.1; = p.G881del on NM_018193.3) | In Frame Del (DEL) | VAF 6/41 reads (15%) | catalogued as rs769118889; called by mutect2, pindel, varscan2
- FBXO21 | c.1139A>G p.N380S | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs772352144, COSV100401646; called by muse, mutect2, varscan2
- FCER2 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as COSV100689525; called by muse, mutect2, varscan2
- FCRL3 | c.2177C>T p.P726L | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); catalogued as COSV100942985, COSV63844004; called by muse, mutect2, varscan2
- FOXB2 | c.798C>G p.F266L | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.028); catalogued as COSV100942320; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100598567; called by muse, mutect2, varscan2
- FRZB | c.140C>A p.P47H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99717310; called by muse, mutect2, varscan2
- FSCB | c.1688C>G p.S563* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV100469040; called by muse, mutect2, varscan2
- FSIP2 | c.19243A>G p.T6415A | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.219); catalogued as COSV100554472; called by muse, mutect2, varscan2
- GAS7 | c.936G>C p.K312N (on ENST00000432992 / NM_201433.2; = p.K172N on NM_003644.3) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60433756, COSV60442529; called by muse, mutect2, varscan2
- GLB1L | c.1007C>G p.S336C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99850361; called by muse, mutect2, varscan2
- GNPTAB | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as COSV100171847; called by muse, mutect2, varscan2
- GPM6A | c.218A>T p.D73V | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.959); catalogued as COSV99703187; called by muse, mutect2, varscan2
- GPR142 | c.127C>G p.Q43E | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV100170720, COSV100170982; called by muse, mutect2, varscan2
- GPR151 | c.714T>A p.N238K | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV99694562; called by muse, mutect2, varscan2
- GREB1 | c.2660G>T p.G887V | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.976); catalogued as COSV52191138, COSV99302468; called by muse, mutect2, varscan2
- GRIN1 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV59294534; called by muse, mutect2, varscan2
- GYPC | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs139780142, CD910525, COSV99391829; called by muse, mutect2, varscan2
- HECTD4 | c.7568C>G p.P2523R | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV101106981; called by muse, mutect2, varscan2
- ICE1 | c.5618G>C p.G1873A | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV99664129; called by muse, mutect2, varscan2
- IFT80 | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100424547; called by muse, mutect2, varscan2
- IRS4 | c.2384A>G p.N795S | Missense Mutation (SNP) | VAF 96/177 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100929481; called by muse, mutect2, varscan2
- KCNG4 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV100376951; called by muse, mutect2, varscan2
- LAMP3 | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV99660412; called by muse, mutect2
- LCE2D | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV100909528, COSV64229271; called by muse, mutect2, varscan2
- LCP1 | c.842C>A p.A281E | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs1218449676, COSV100549773; called by muse, mutect2, varscan2
- MDGA2 | c.2232C>G p.I744M (on ENST00000399232 / NM_001113498.2; = p.I446M on NM_182830.4) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV100636596; called by muse, mutect2, varscan2
- MED23 | c.3032A>G p.Y1011C | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs767571500, COSV100644837; called by muse, mutect2, varscan2
- MEX3D | c.821C>T p.T274I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV101183475; called by muse, mutect2, varscan2
- MKI67 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100896334; called by muse, mutect2, varscan2
- MKRN3 | c.733T>A p.Y245N | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100090936; called by muse, mutect2, varscan2
- MROH8 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as COSV99456830; called by muse, mutect2, varscan2
- MUC16 | c.7942C>A p.P2648T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV67483210; called by muse, mutect2, varscan2
- MUTYH | c.146C>G p.S49C | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV100587970, COSV62744019; called by muse, mutect2, varscan2
- MVP | c.2560G>A p.E854K | Missense Mutation (SNP) | VAF 76/179 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs766972215, COSV100651522; called by muse, mutect2, varscan2
- MYH1 | c.2189A>G p.N730S | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV99875283; called by muse, mutect2, varscan2
- MYO5C | c.2671G>T p.V891F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99954326; called by mutect2, varscan2
- MYO5C | c.2670G>T p.R890S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV55912907; called by mutect2, varscan2
- NAA16 | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.277); catalogued as COSV101038269; called by muse, mutect2, varscan2
- NECTIN2 | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 13/24 reads (54%) | catalogued as COSV99374846; called by muse, mutect2, varscan2
- NEUROD6 | c.68G>C p.R23T | Missense Mutation (SNP) | VAF 84/231 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.95); catalogued as COSV51770132; called by muse, mutect2, varscan2
- NINL | c.3202G>T p.V1068F | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs199894600, COSV99624960; called by muse, mutect2, varscan2
- NMBR | c.379G>C p.V127L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV104382245, COSV99237157; called by muse, mutect2, varscan2
- NODAL | c.1017G>A p.M339I | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99755385; called by muse, mutect2, varscan2
- NUMA1 | c.952G>T p.E318* | Nonsense Mutation (SNP) | VAF 22/75 reads (29%) | catalogued as COSV100705925; called by muse, mutect2, varscan2
- NUP214 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.842); catalogued as COSV100845191; called by muse, mutect2, varscan2
- OR2B11 | c.754G>T p.V252F | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368268590, COSV100275578, COSV59509504; called by muse, mutect2, varscan2
- OR2T2 | c.79C>A p.L27I | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100737615, COSV61618224; called by muse, mutect2, varscan2
- OR9K2 | c.954A>T p.K318N (on ENST00000305377; = p.K296N on NM_001005243.1) | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV100543778; called by muse, mutect2, varscan2
- OTOF | c.482G>T p.R161L | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.033); catalogued as rs141475833, COSV99716952; called by muse, mutect2, varscan2
- OVCH1 | c.1687A>G p.I563V | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.099); catalogued as rs753280747, COSV100548339; called by muse, mutect2, varscan2
- P3H1 | c.1693C>T p.H565Y | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.337); catalogued as rs1340455468, COSV99354945; called by muse, mutect2, varscan2
- PARD3B | c.908C>G p.S303C | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.471); catalogued as COSV100592697, COSV62510773; called by muse, mutect2, varscan2
- PCNX1 | c.739C>T p.H247Y | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as rs754919456, COSV99454806; called by muse, mutect2, varscan2
- PDHA2 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759206654, COSV99756669; called by muse, mutect2, varscan2
- PFKP | c.871-2A>T p.X291_splice | Splice Site (SNP) | VAF 39/95 reads (41%) | catalogued as COSV101127048; called by muse, mutect2, varscan2
- PGM2 | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101126554, COSV67938951; called by muse, mutect2, varscan2
- PKHD1L1 | c.4638C>A p.N1546K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.147); catalogued as rs1224593507, COSV101005722, COSV99058828; called by muse, mutect2, varscan2
- PNISR | c.744G>C p.Q248H | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1328450014, COSV100984329; called by muse, mutect2, varscan2
- POLR3A | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as rs1392081224, COSV100965574; called by muse, mutect2, varscan2
- POM121C | c.1092G>C p.K364N (on ENST00000607367; = p.K122N on NM_001099415.3) | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99992534; called by muse, mutect2, varscan2
- POMGNT1 | c.1967C>T p.A656V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | PolyPhen benign (0.164); catalogued as COSV100915454; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as COSV99461023; called by muse, mutect2, varscan2
- PRDM5 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV99309591, COSV99310110; called by muse, mutect2, varscan2
- QTRT2 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV99846844; called by muse, mutect2, varscan2
- RESF1 | c.4637A>T p.D1546V | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100440229; called by muse, mutect2, varscan2
- RFTN2 | c.532G>T p.G178* | Nonsense Mutation (SNP) | VAF 37/141 reads (26%) | catalogued as COSV99695372; called by muse, mutect2, varscan2
- RGS2 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.325); catalogued as rs1439816824, COSV99343304; called by muse, mutect2, varscan2
- RPRD2 | c.2051G>C p.G684A | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.234); catalogued as COSV100954985; called by muse, mutect2, varscan2
- RREB1 | c.4781A>G p.N1594S | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV100619219; called by muse, mutect2, varscan2
- RSPO1 | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.157); catalogued as COSV62975203; called by muse, varscan2
- SACS | c.9409G>A p.D3137N | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV66537785; called by muse, mutect2, varscan2
- SAMD13 | c.365C>G p.S122* (on ENST00000370671; = p.S116* on NM_001010971.3) | Nonsense Mutation (SNP) | VAF 27/89 reads (30%) | catalogued as COSV101043033; called by muse, mutect2, varscan2
- SEMA3A | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 33/262 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as rs566466269, COSV54892416; called by muse, mutect2, varscan2
- SEMA3E | c.1465G>T p.V489F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as rs1562761096, COSV100317834; called by muse, mutect2
- SF3B3 | c.448G>T p.A150S | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV100209690; called by muse, mutect2, varscan2
- SH3RF3 | c.676A>T p.K226* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100512510; called by muse, mutect2, varscan2
- SLC11A1 | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51917008; called by muse, mutect2, varscan2
- SLC1A3 | c.725A>T p.N242I | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99467237; called by muse, mutect2, varscan2
- SLC2A11 | c.1027G>T p.G343C (on ENST00000345044 / NM_001024938.4; = p.G350C on NM_030807.5) | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as COSV55393704, COSV99741278; called by muse, mutect2, varscan2
- SLC8A3 | c.938G>T p.R313L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63523008, COSV63523018; called by muse, mutect2, varscan2
- SOX5 | c.2030A>T p.Y677F | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV100506345; called by muse, mutect2, varscan2
- SPAG16 | c.1137G>T p.L379F | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.063); catalogued as COSV100530818; called by muse, mutect2, varscan2
- SPEF2 | c.2210T>C p.L737P | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100606711; called by muse, mutect2, varscan2
- SPTBN1 | c.2072G>C p.S691T | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as COSV100442081; called by muse, mutect2, varscan2
- SREBF1 | c.2154C>G p.I718M | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV99888536; called by muse, mutect2
- SRPX | c.210G>T p.R70S | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV100655970; called by muse, mutect2, varscan2
- STAMBP | c.988A>T p.T330S | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as COSV100277638; called by muse, mutect2, varscan2
- STX7 | c.424C>G p.L142V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.387); catalogued as COSV100908414; called by muse, mutect2, varscan2
- SYTL5 | c.1210G>A p.V404M | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1302445386, COSV99936992; called by muse, mutect2, varscan2
- TAAR2 | c.1045G>C p.E349Q (on ENST00000367931 / NM_001033080.1; = p.E304Q on NM_014626.3) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.005); catalogued as COSV51578886, COSV99255567; called by muse, mutect2, varscan2
- TACC2 | c.2441T>C p.I814T | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100551859; called by muse, mutect2, varscan2
- TAS2R3 | c.579A>T p.L193F | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.066); catalogued as rs1371859716, COSV99924487; called by muse, mutect2, varscan2
- TBCC | c.17G>T p.C6F | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs375456367, COSV99773941; called by muse, mutect2, varscan2
- TCF20 | c.4312C>T p.R1438C | Missense Mutation (SNP) | VAF 98/218 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); catalogued as rs771336001, COSV59496359; called by muse, mutect2, varscan2
- TFB2M | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.113); catalogued as COSV100829824; called by muse, mutect2, varscan2
- TFRC | c.1004A>G p.Q335R | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100786419; called by muse, mutect2, varscan2
- TIE1 | c.901C>A p.Q301K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as COSV100992033; called by muse, mutect2, varscan2
- TMC3 | c.375G>T p.M125I | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV100845856, COSV100845864; called by muse, varscan2
- TMEM168 | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as rs529190744, COSV100454556; called by muse, mutect2, varscan2
- TNRC6A | c.4838G>A p.R1613H | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.996); catalogued as rs764526822, COSV100169629; called by muse, mutect2, varscan2
- TPR | c.1724+1G>A p.X575_splice | Splice Site (SNP) | VAF 17/56 reads (30%) | catalogued as COSV100823742; called by muse, mutect2, varscan2
- TRMT13 | c.167G>C p.R56T | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99790693; called by muse, mutect2, varscan2
- TRNT1 | c.630C>A p.D210E | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99214101; called by muse, mutect2, varscan2
- TRPV4 | c.241A>C p.N81H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.467); catalogued as COSV99924495; called by muse, mutect2, varscan2
- TSC22D2 | c.2164A>G p.R722G | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100721198; called by muse, mutect2, varscan2
- TTC14 | c.1259A>C p.D420A | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.473); catalogued as COSV99931910; called by muse, mutect2, varscan2
- TTN | c.56494C>T p.P18832S (on ENST00000591111; = p.P11408S on NM_003319.4) | Missense Mutation (SNP) | VAF 29/111 reads (26%) | PolyPhen probably damaging (0.998); catalogued as COSV100600818; called by muse, mutect2, varscan2
- TUBGCP6 | c.4288C>T p.R1430W | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs754895676, COSV99955106; called by muse, mutect2, varscan2
- UBA2 | c.620C>G p.S207C | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55830160, COSV99875391; called by muse, mutect2, varscan2
- USH2A | c.8474G>T p.G2825V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV100231499; called by muse, mutect2, varscan2
- USH2A | c.8473G>T p.G2825C | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV100231501; called by muse, mutect2, varscan2
- VAMP7 | c.29G>C p.R10T | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99387722, COSV99387785; called by muse, mutect2, varscan2
- YTHDF1 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100945551; called by muse, mutect2, varscan2
- ZBTB46 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV55508601, COSV55513852; called by muse, mutect2, varscan2
- ZCCHC8 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777624068, COSV100288516; called by muse, mutect2, varscan2
- ZDHHC6 | c.76A>G p.I26V | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV101024351; called by muse, mutect2, varscan2
- ZNF100 | c.770G>C p.G257A | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as COSV99973856, COSV99974176; called by muse, mutect2, varscan2
- ZNF169 | c.435G>C p.E145D | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100566173; called by muse, mutect2, varscan2
- ZNF19 | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV99867174; called by muse, mutect2
- ZNF233 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100492157; called by muse, mutect2, varscan2
- ZNF263 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as rs760565822, COSV99526778; called by muse, mutect2, varscan2
- ZNF451 | c.959G>A p.C320Y | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100674773; called by muse, mutect2, varscan2
- ZNF574 | c.2077G>T p.G693W | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV99725878; called by muse, mutect2, varscan2
- ZNF574 | c.2078G>T p.G693V | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV55905531, COSV99725880; called by muse, mutect2, varscan2
- ZZZ3 | c.226A>T p.T76S | Missense Mutation (SNP) | VAF 63/251 reads (25%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV100890242; called by muse, mutect2, varscan2
- ADCK1 | c.1464_1470del p.N489Gfs*12 | Frame Shift Del (DEL) | VAF 25/90 reads (28%) | called by mutect2, pindel, varscan2
- CFAP47 | c.1575del p.V527Lfs*2 | Frame Shift Del (DEL) | VAF 26/60 reads (43%) | called by mutect2, pindel, varscan2
- DZIP3 | c.2969del p.P990Rfs*14 | Frame Shift Del (DEL) | VAF 132/352 reads (38%) | called by mutect2, pindel, varscan2
- FAM83F | c.1285dup p.R429Pfs*38 | Frame Shift Ins (INS) | VAF 9/45 reads (20%) | called by pindel, varscan2
- GARNL3 | c.92C>G p.P31R | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- KDM4A | c.1962_1963dup p.K655Rfs*19 | Frame Shift Ins (INS) | VAF 19/77 reads (25%) | called by mutect2, pindel, varscan2
- KLF17 | c.581del p.P194Rfs*40 | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | called by mutect2, pindel, varscan2
- LY6D | c.63del p.R22Afs*33 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- OR11H1 | c.407A>T p.Y136F | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PDIA6 | c.998+1del p.X333_splice | Splice Site (DEL) | VAF 135/375 reads (36%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1722_1729del p.K575Rfs*24 (on ENST00000521381 / NM_181523.3; = p.K305Rfs*24 on NM_181504.4) | Frame Shift Del (DEL) | VAF 15/68 reads (22%) | called by mutect2, pindel*, varscan2*
- PLXNA2 | c.5305G>T p.A1769S | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.39); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN5A | c.5505del p.I1836Sfs*8 (on ENST00000333535 / NM_198056.3; = p.I1835Sfs*8 on NM_000335.5) | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | called by mutect2, pindel, varscan2
- AADAC | c.408T>C p.L136= | Silent (SNP) | VAF 39/136 reads (29%) | catalogued as COSV99233142; called by muse, mutect2, varscan2
- ACSM1 | c.393C>T p.C131= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as rs1201048659, COSV99532677; called by muse, mutect2, varscan2
- AMDHD1 | c.903T>A p.S301= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV99900246; called by muse, mutect2, varscan2
- ANKRD1 | c.306T>A p.T102= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV100792298; called by mutect2, varscan2
- ANO7 | c.1914C>A p.I638= (on ENST00000274979; = p.I584= on NM_001370694.2) | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV99237797; called by muse, mutect2, varscan2
- ARHGAP39 | c.2760G>T p.L920= (on ENST00000276826 / NM_001308208.2; = p.L951= on NM_025251.2) | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV99430563; called by muse, mutect2, varscan2
- CAND1 | c.1641C>T p.V547= | Silent (SNP) | VAF 36/163 reads (22%) | catalogued as COSV101607303; called by muse, mutect2, varscan2
- CEBPZ | c.219A>G p.K73= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs909396917, COSV99135467; called by muse, mutect2, varscan2
- CELSR2 | c.171C>G p.L57= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs1189193745, COSV99603343; called by muse, mutect2, varscan2
- DIDO1 | c.300G>A p.T100= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs141299956; called by muse, mutect2, varscan2
- ENPP5 | c.447C>T p.R149= | Silent (SNP) | VAF 40/141 reads (28%) | catalogued as COSV100040375; called by muse, mutect2, varscan2
- EXD1 | c.498C>T p.C166= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100153545; called by muse, mutect2, varscan2
- GHSR | c.918C>G p.L306= | Silent (SNP) | VAF 40/145 reads (28%) | catalogued as COSV53839591, COSV99576800; called by muse, mutect2, varscan2
- GPR37L1 | c.225C>T p.G75= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100938528; called by muse, mutect2, varscan2
- HELB | c.1032G>T p.V344= | Silent (SNP) | VAF 73/278 reads (26%) | catalogued as COSV99921683; called by muse, mutect2, varscan2
- KLHL13 | c.384A>G p.K128= | Silent (SNP) | VAF 29/49 reads (59%) | catalogued as COSV99451318; called by muse, mutect2, varscan2
- LGSN | c.795G>A p.Q265= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV101040378; called by muse, mutect2, varscan2
- LIFR | c.123A>G p.Q41= | Silent (SNP) | VAF 36/122 reads (30%) | catalogued as COSV54701091; called by muse, mutect2, varscan2
- LRCH4 | c.111C>T p.A37= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as rs1488323476, COSV99575116; called by muse, mutect2
- MAOB | c.1518T>A p.A506= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV100955956; called by muse, mutect2, varscan2
- MNDA | c.1107C>A p.L369= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV100933277; called by muse, mutect2, varscan2
- MTUS2 | c.1461G>C p.L487= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV101462130; called by muse, mutect2, varscan2
- MYH6 | c.3835C>A p.R1279= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs751426149, COSV100676386, COSV62447606; called by muse, mutect2, varscan2
- NALCN | c.1440C>T p.L480= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV51949997, COSV99213690; called by muse, mutect2, varscan2
- OR2D2 | c.141C>T p.S47= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV55056743, COSV55058786; called by muse, mutect2, varscan2
- ORM1 | c.156C>T p.N52= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as rs551088472, COSV52278388; called by muse, mutect2, varscan2
- PARVB | c.222G>A p.T74= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as rs147225622; called by muse, mutect2, varscan2
- PCSK2 | c.1725C>A p.V575= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV99359045; called by muse, mutect2, varscan2
- PDCD6 | c.237C>A p.G79= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV99372622; called by muse, mutect2, varscan2
- PLG | c.159T>C p.C53= | Silent (SNP) | VAF 33/135 reads (24%) | catalogued as COSV99804380; called by muse, mutect2, varscan2
- POLR1D | c.135C>T p.H45= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as rs1179947533, COSV100265910; called by muse, mutect2, varscan2
- PROM2 | c.264G>A p.L88= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs1473064899, COSV100468781; called by muse, mutect2, varscan2
- PSEN1 | c.99A>G p.R33= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99997681; called by muse, varscan2
- RGS6 | c.678A>G p.P226= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100665525; called by muse, mutect2, varscan2
- RPRD1B | c.330C>T p.I110= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV100987202; called by muse, mutect2, varscan2
- RUSC1 | c.414C>A p.I138= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV99429592; called by muse, mutect2, varscan2
- S100A13 | c.63C>T p.F21= | Silent (SNP) | VAF 55/192 reads (29%) | catalogued as COSV99417876; called by muse, mutect2, varscan2
- SEC63 | c.1149C>T p.P383= | Silent (SNP) | VAF 46/153 reads (30%) | catalogued as COSV100938336; called by muse, mutect2, varscan2
- SH3TC1 | c.528C>T p.F176= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99794583; called by muse, mutect2, varscan2
- SLC11A1 | c.168G>T p.R56= | Silent (SNP) | VAF 26/140 reads (19%) | catalogued as COSV99261958; called by muse, mutect2, varscan2
- SLC22A2 | c.927A>G p.K309= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV100870955; called by muse, mutect2
- SLC36A2 | c.1451G>A p.*484= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV100078999; called by muse, mutect2, varscan2
- SLC9A4 | c.2248C>T p.L750= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99762812, COSV99763179; called by muse, mutect2, varscan2
- SPATA17 | c.381C>G p.T127= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as COSV100860967; called by muse, mutect2, varscan2
- SPATC1 | c.1515G>C p.V505= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV101084824; called by muse, mutect2, varscan2
- SYNJ2 | c.171C>G p.L57= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100840086; called by muse, mutect2, varscan2
- TASOR2 | c.5802C>G p.L1934= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs1340820254, COSV100050131; called by muse, mutect2, varscan2
- THOC2 | c.3312A>C p.L1104= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV99832993; called by muse, mutect2, varscan2
- TRPV3 | c.1467T>C p.F489= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV100027566; called by muse, mutect2, varscan2
- USP33 | c.1320T>C p.P440= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV100657042; called by muse, mutect2, varscan2
- ZMYM4 | c.2823G>A p.L941= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV100109829, COSV58917878; called by muse, mutect2, varscan2
- LINC01559 | n.286T>A | RNA (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- LSR | c.*2C>G | 3'UTR (SNP) | VAF 97/166 reads (58%) | catalogued as rs138382483, COSV99723453; called by muse, mutect2, varscan2
- NCOA7 | c.2245-1619_2245-1618insA | Intron (INS) | VAF 20/120 reads (17%) | called by mutect2, pindel, varscan2
- PRR12 | chr19:49594544 C>T | 5'Flank (SNP) | VAF 28/73 reads (38%) | catalogued as COSV99882319; called by muse, mutect2, varscan2
- XIRP2 | c.*1025G>T | 3'UTR (SNP) | VAF 21/63 reads (33%) | catalogued as COSV54701213, COSV99740284; called by muse, mutect2, varscan2
